Gene-level copy-number profile of tumor specimen TCGA-E1-5307-01A from TCGA case TCGA-E1-5307, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 62.5 years (22,837 days).
Specimen TCGA-E1-5307-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.7d26e9bb-694e-429d-9a82-33faa81f987c.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-E1-5307-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 390 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1c1b586b-e9eb-4123-9920-ee4452030022

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,619; copy number 1: 11,304; copy number 2: 44,613; copy number 3: 1,209; copy number 4: 399; copy number 5: 83; copy number 6: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-E1-5307-01A-01D-1892-01): tumor purity 0.19, ploidy 3.75, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 507 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–9,018,899, 124 genes (broad region; genes not listed).
- chr9:1,977,784–10,612,723, 116 genes (within-gene range 0–1) (broad region; genes not listed).
- chr16:35,134,514–35,154,366, 3 genes: VN1R69P, AC023824.5, AC023824.6.
- chr18:47,390–9,960,021, 206 genes (within-gene range 0–2) (broad region; genes not listed).
- chr18:77,421,619–80,247,514, 58 genes: AC124254.2, AC124254.1, BDP1P, AC123786.1, AC123786.2, AC123786.3, RNA5SP461, LINC01029, AC134978.1, RNU6-655P, AC107892.1, AC087399.1, AC012572.1, Y_RNA, AC044873.1, AC091027.2, AC091027.1, AC091027.3, LINC01896, SALL3, ATP9B, AC099689.3, AC125437.1, AC125437.2, AC125437.3, AC104423.1, AC023090.1, AC023090.2, NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2, AC018445.6, AC068473.3, AC068473.4, AC068473.1, AC068473.5, CTDP1, AC068473.2, AC021594.1, AC021594.2, KCNG2, AC114341.1, SLC66A2, AC114341.2, HSBP1L1, TXNL4A, AC090360.1, RBFA, RBFADN, SLC25A6P4, ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 89 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,670,652, 6 genes, copy number 6 (within-gene range 2–6): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr14:18,333,726–19,957,996, 83 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,717. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
